Somatic mutation profile of tumor specimen MP2PRT-PARPWB-TMP1-A (aliquot MP2PRT-PARPWB-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARPWB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.7 years (1,723 days).
Specimen MP2PRT-PARPWB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce01b7b0-3f66-4f3f-b92f-e615664ed4de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPWB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPWB-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2c12a545-beb2-4609-81ac-8f907572c3a1

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Nonsense Mutation 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 70/336 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DCAF8L1 | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 200/454 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); catalogued as rs749236143, COSV71595229; called by muse, varscan2
- HAS1 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 48/564 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767651246; called by muse, mutect2
- HTR3E | c.1259C>T p.S420L (on ENST00000415389 / NM_001256613.1; = p.S435L on NM_182589.2) | Missense Mutation (SNP) | VAF 45/388 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs373657273; called by muse, mutect2, varscan2
- IGHM | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 82/472 reads (17%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.497); catalogued as rs1175701374; called by muse, mutect2, varscan2
- IL36A | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 35/183 reads (19%) | catalogued as rs780011138, COSV52082815; called by muse, mutect2, varscan2
- LGI2 | c.622G>A p.V208M | Missense Mutation (SNP) | VAF 44/468 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs375887654; called by muse, mutect2
- MYOM3 | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 45/392 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs375914516; called by muse, varscan2
- SLC6A2 | c.1369G>A p.A457T | Missense Mutation (SNP) | VAF 65/249 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as rs121918126, CM000572; called by muse, mutect2, varscan2
- THBS2 | c.3187G>A p.V1063M | Missense Mutation (SNP) | VAF 121/655 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs769806537; called by muse, mutect2, varscan2
- ZNF365 | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 96/569 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs184098438; called by muse, mutect2, varscan2
- DDX5 | c.47T>G p.F16C | Missense Mutation (SNP) | VAF 13/317 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.157); called by muse, mutect2
- SIN3A | c.384_388delinsGG p.Y129_L130delinsV | In Frame Del (DEL) | VAF 76/217 reads (35%) | called by pindel, varscan2*
- TNIK | c.1767T>A p.D589E | Missense Mutation (SNP) | VAF 50/236 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASAH2 | c.840A>G p.E280= | Silent (SNP) | VAF 34/358 reads (9%) | called by muse, mutect2
- EPN1 | c.273C>T p.R91= | Silent (SNP) | VAF 73/249 reads (29%) | catalogued as rs770618655; called by muse, mutect2, varscan2
- NOC2L | c.90C>A p.S30= | Silent (SNP) | VAF 190/459 reads (41%) | called by muse, mutect2, varscan2
- RASIP1 | c.1650C>T p.R550= | Silent (SNP) | VAF 24/656 reads (4%) | called by muse, mutect2
- IGKV1OR2-108 | chr2:113406872 ins ACTC | 3'Flank (INS) | VAF 57/137 reads (42%) | called by mutect2, pindel, varscan2
